Somatic mutation profile of tumor specimen TCGA-IB-7886-01A (aliquot TCGA-IB-7886-01A-11D-2154-08) from TCGA case TCGA-IB-7886, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 80.3 years (29,319 days).
Specimen TCGA-IB-7886-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce44b8e9-4513-4278-ab83-1006cd745520.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7886-10A (Blood Derived Normal), aliquot TCGA-IB-7886-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ffbea22-37a4-476e-8035-8f16b5ab8a71

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Frame Shift Ins 3, Splice Site 1, Splice Region 1, Nonsense Mutation 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 44/105 reads (42%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.4880G>A p.R1627Q | Missense Mutation (SNP) | VAF 37/148 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs767331775, COSV71672487; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 174/247 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH16A1 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 276/1059 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99513214; called by muse, mutect2, varscan2
- ANXA7 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV100873509; called by muse, mutect2, varscan2
- ARMCX1 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100863243; called by muse, mutect2, varscan2
- CDH11 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99219720; called by muse, mutect2, varscan2
- CDK14 | c.369G>C p.S123= (on ENST00000380050 / NM_001287135.2; = p.S105= on NM_012395.3) | Splice Region (SNP) | VAF 217/545 reads (40%) | catalogued as COSV56028454, COSV56040466; called by muse, mutect2, varscan2
- CEACAM3 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 426/1287 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV55760643, COSV99705113; called by muse, mutect2, varscan2
- COL22A1 | c.3862G>A p.G1288S | Missense Mutation (SNP) | VAF 90/558 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769380944, COSV100277118, COSV57341198; called by muse, mutect2, varscan2
- COL5A1 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs149912828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4F22 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 220/534 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200005567; called by muse, mutect2, varscan2
- FLRT2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 330/840 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs149005998; called by muse, mutect2, varscan2
- FOXG1 | c.710A>G p.K237R | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487064; called by muse, mutect2, varscan2
- INSR | c.4127T>G p.L1376W | Missense Mutation (SNP) | VAF 168/807 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100253459; called by muse, mutect2, varscan2
- KHDRBS3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 94/687 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.259); catalogued as rs773950506, COSV100879014; called by muse, mutect2, varscan2
- LMX1B | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs970901093, COSV100827283; called by muse, mutect2
- LYZL4 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99821311; called by muse, mutect2, varscan2
- MROH7 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs367669775; called by muse, mutect2, varscan2
- NUAK1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 204/788 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs757681052, COSV99777317; called by muse, mutect2, varscan2
- PAPPA2 | c.4884+1G>C p.X1628_splice | Splice Site (SNP) | VAF 137/691 reads (20%) | catalogued as COSV100868623; called by muse, mutect2, varscan2
- PDE10A | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 185/657 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV63094713; called by muse, mutect2, varscan2
- PIK3CG | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 91/430 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100782543; called by muse, mutect2, varscan2
- PLEKHH1 | c.2596G>A p.V866M | Missense Mutation (SNP) | VAF 200/557 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs201045091, COSV100233471; called by muse, mutect2, varscan2
- QARS1 | c.1951G>T p.V651F | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV100070268; called by muse, mutect2, varscan2
- SBF2 | c.3596G>A p.G1199E | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99815698; called by muse, mutect2, varscan2
- SLC18A2 | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 75/437 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100041859; called by muse, mutect2, varscan2
- SLC30A1 | c.380A>T p.N127I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100879168; called by muse, mutect2, varscan2
- SORCS3 | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV100865650; called by muse, mutect2, varscan2
- SUGT1 | c.964G>C p.D322H (on ENST00000343788 / NM_001130912.3; = p.D290H on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 288/566 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100139687, COSV59422171; called by muse, mutect2, varscan2
- TNXB | c.5746G>A p.A1916T (on ENST00000647633; = p.A1669T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.201); catalogued as rs778890919, COSV100926637; called by muse, mutect2, varscan2
- TP53 | c.167_168dup p.D57Kfs*67 | Frame Shift Ins (INS) | VAF 473/1121 reads (42%) | catalogued as COSV53300967; called by mutect2, pindel, varscan2
- ZMIZ2 | c.1262T>G p.L421W | Missense Mutation (SNP) | VAF 63/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99537190; called by muse, mutect2, varscan2
- ZNF675 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 149/380 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs552345271, COSV63094858; called by muse, mutect2, varscan2
- ZNF99 | c.2263C>A p.H755N | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101233967, COSV68056421, COSV68056732; called by muse, mutect2, varscan2
- FBN3 | c.5876_5877insTCCCCATGG p.G1959_F1960insPHG | In Frame Ins (INS) | VAF 34/137 reads (25%) | called by pindel, varscan2
- MUC16 | c.24318dup p.E8107* | Frame Shift Ins (INS) | VAF 219/669 reads (33%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1234dup p.Y412Lfs*17 | Frame Shift Ins (INS) | VAF 93/330 reads (28%) | called by mutect2, pindel, varscan2
- ABCB1 | c.561T>C p.G187= | Silent (SNP) | VAF 101/539 reads (19%) | catalogued as COSV99714340; called by muse, mutect2, varscan2
- ADGRV1 | c.5154C>T p.D1718= | Silent (SNP) | VAF 22/217 reads (10%) | catalogued as rs371138490; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7530A>G p.K2510= | Silent (SNP) | VAF 79/383 reads (21%) | catalogued as COSV99784433; called by muse, mutect2, varscan2
- BCL11B | c.2403C>T p.C801= (on ENST00000357195 / NM_001282237.2; = p.C730= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs780100734, COSV100595896; called by muse, mutect2, varscan2
- CIC | c.3552C>A p.I1184= | Silent (SNP) | VAF 75/245 reads (31%) | catalogued as COSV50548110, COSV99360269; called by muse, mutect2, varscan2
- CWH43 | c.1213T>C p.L405= | Silent (SNP) | VAF 93/347 reads (27%) | catalogued as rs1488046121, COSV99894125; called by muse, mutect2, varscan2
- DAB2 | c.990G>A p.P330= | Silent (SNP) | VAF 105/627 reads (17%) | catalogued as rs199558080; called by muse, mutect2, varscan2
- FUS | c.874C>T p.L292= | Silent (SNP) | VAF 293/1519 reads (19%) | catalogued as rs1309427963, COSV99569004; called by muse, mutect2, varscan2
- GPRC5B | c.912G>A p.T304= | Silent (SNP) | VAF 71/407 reads (17%) | catalogued as rs199673129, COSV100315296; called by muse, mutect2, varscan2
- HMMR | c.1032A>T p.S344= | Silent (SNP) | VAF 26/214 reads (12%) | catalogued as COSV100701052; called by muse, mutect2, varscan2
- NFRKB | c.3579G>A p.Q1193= (on ENST00000446488 / NM_001143835.2; = p.Q1218= on NM_006165.3) | Silent (SNP) | VAF 56/425 reads (13%) | catalogued as COSV100452085; called by muse, mutect2, varscan2
- PLCD3 | c.1488G>A p.S496= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs61045085, COSV100504008; called by muse, varscan2
- PLEKHA3 | c.888A>T p.P296= | Silent (SNP) | VAF 57/399 reads (14%) | catalogued as COSV99317895; called by muse, mutect2, varscan2
- TTN | c.33798C>T p.P11266= (on ENST00000591111; = p.P10339= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 538/1451 reads (37%) | catalogued as rs1302696503, COSV100629407; called by muse, mutect2, varscan2
- UBTFL2 | n.778C>T | RNA (SNP) | VAF 156/609 reads (26%) | catalogued as rs767760358; called by muse, mutect2, varscan2
